Somatic mutation profile of tumor specimen C3N-04312-02 (aliquot CPT0285670006) from CPTAC case C3N-04312, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 51.8 years (18,938 days).
Specimen C3N-04312-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 34790996-edac-435f-9ffc-406ea2faaf5a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-04312-32 (Blood Derived Normal), aliquot CPT0280980002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c57eb0ba-74e5-4e0d-8948-a1fae168df85

The open-access MAF lists 108 somatic variants for this specimen: 70 protein-altering or splice-affecting, 27 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 27, Intron 8, Nonsense Mutation 5, Frame Shift Del 5, 3'UTR 2, In Frame Del 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 983/6000 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs769696078, COSV51770322, COSV99297135; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACMSD | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 113/254 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0.189); catalogued as rs779680562, COSV51607683; called by muse, mutect2, varscan2
- ADAMTS15 | c.2474T>C p.V825A | Missense Mutation (SNP) | VAF 72/204 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs1428706604, COSV54508929; called by muse, mutect2, varscan2
- ADAMTS7 | c.4220C>T p.P1407L | Missense Mutation (SNP) | VAF 29/247 reads (12%) | SIFT tolerated (0.91); PolyPhen benign (0.001); catalogued as rs762903913; called by muse, mutect2
- AFF2 | c.716C>T p.P239L | Missense Mutation (SNP) | VAF 97/329 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as rs199567128, COSV60665424; called by muse, mutect2, varscan2
- AMDHD1 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 132/328 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs1178699284, COSV57140901; called by muse, mutect2, varscan2
- AR | c.2179C>T p.R727C | Missense Mutation (SNP) | VAF 133/561 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781301298, COSV65962818; called by muse, mutect2, varscan2
- C4orf50 | c.50G>A p.R17Q (on ENST00000324058; = p.R1249Q on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 108/241 reads (45%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as rs146706396, COSV100136078; called by muse, mutect2, varscan2
- CACNA1H | c.2686C>T p.R896C | Missense Mutation (SNP) | VAF 140/417 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1047092055; called by muse, mutect2, varscan2
- CLEC4M | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 101/446 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs376066614; called by muse, mutect2, varscan2
- CPS1 | c.520C>T p.R174W | Missense Mutation (SNP) | VAF 60/215 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1553509661, CM1510933, COSV51828095; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTCF | c.829C>T p.R277W | Missense Mutation (SNP) | VAF 20/474 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV50476541; called by muse, mutect2
- DCAF12L2 | c.1289C>T p.A430V | Missense Mutation (SNP) | VAF 14/428 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV63580722, COSV63582449, COSV63583358; called by muse, mutect2
- FAM120C | c.1823T>C p.L608S | Missense Mutation (SNP) | VAF 21/456 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60257683; called by muse, mutect2
- FCGBP | c.8806G>A p.V2936I | Missense Mutation (SNP) | VAF 87/850 reads (10%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.817); catalogued as rs1417669528; called by muse, mutect2, varscan2
- HAVCR1 | c.575C>T p.T192M | Missense Mutation (SNP) | VAF 153/470 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs768728879, COSV59400606; called by muse, mutect2, varscan2
- KIAA1755 | c.1990G>A p.A664T | Missense Mutation (SNP) | VAF 61/235 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.027); catalogued as rs950407888; called by muse, mutect2, varscan2
- KIF4A | c.2182C>T p.R728W | Missense Mutation (SNP) | VAF 67/281 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1240274269, COSV65542698; called by muse, mutect2, varscan2
- KISS1 | c.263C>T p.A88V | Missense Mutation (SNP) | VAF 104/282 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.054); catalogued as rs760697034; called by muse, mutect2, varscan2
- KLHL26 | c.442G>A p.V148M | Missense Mutation (SNP) | VAF 145/450 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs566132604, COSV56317103; called by muse, mutect2, varscan2
- KRT26 | c.277C>T p.R93C | Missense Mutation (SNP) | VAF 126/336 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372502675, COSV56970677, COSV56973714; called by muse, mutect2, varscan2
- KRTAP4-11 | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 107/516 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1338577565; called by muse, varscan2
- MRGPRF | c.943C>T p.R315W | Missense Mutation (SNP) | VAF 68/161 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1274824700, COSV57995817; called by muse, mutect2, varscan2
- MS4A4E | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.711); catalogued as rs928498801; called by mutect2, varscan2
- NOS1 | c.3697G>A p.V1233M | Missense Mutation (SNP) | VAF 50/111 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs757780284, COSV57607043; called by muse, mutect2, varscan2
- PLAT | c.137C>T p.T46M | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs375926300, COSV54276924; called by muse, mutect2, varscan2
- PLEKHG4B | c.448G>A p.G150S (on ENST00000283426; = p.G506S on NM_052909.5) | Missense Mutation (SNP) | VAF 133/347 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs371569763; called by muse, mutect2, varscan2
- PNMA5 | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.477); catalogued as rs782553555, COSV62625985; called by muse, mutect2, varscan2
- PRDM16 | c.1258C>T p.R420C | Missense Mutation (SNP) | VAF 110/270 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54599414; called by muse, mutect2, varscan2
- RAD51D | c.758G>T p.R253L | Missense Mutation (SNP) | VAF 15/439 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV60004762; called by muse, mutect2
- SLC2A14 | c.1460G>A p.R487Q | Missense Mutation (SNP) | VAF 153/459 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.022); catalogued as rs770162236, COSV61586441; called by muse, mutect2, varscan2
- SLIT3 | c.2515C>T p.P839S | Missense Mutation (SNP) | VAF 98/286 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as rs867928943; called by muse, mutect2, varscan2
- SNRNP27 | c.142C>T p.R48* | Nonsense Mutation (SNP) | VAF 84/234 reads (36%) | catalogued as rs1183028727; called by muse, mutect2, varscan2
- SPEF1 | c.568del p.E190Sfs*16 | Frame Shift Del (DEL) | VAF 93/490 reads (19%) | catalogued as COSV99059607; called by mutect2, pindel, varscan2
- TAF1 | c.4409G>A p.R1470H (on ENST00000373790 / NM_138923.4; = p.R1491H on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/246 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV52130359; called by muse, mutect2, varscan2
- TAT | c.1090C>T p.R364W | Missense Mutation (SNP) | VAF 218/581 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); catalogued as rs371975183; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TNS3 | c.3496C>T p.Q1166* | Nonsense Mutation (SNP) | VAF 803/4556 reads (18%) | catalogued as COSV60788990; called by muse, mutect2, varscan2
- UTP14C | c.1936C>T p.R646C | Missense Mutation (SNP) | VAF 122/350 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.052); catalogued as rs764932517, COSV73000607; called by muse, mutect2, varscan2
- WFDC9 | c.25G>A p.V9I | Missense Mutation (SNP) | VAF 48/216 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs370373417; called by muse, mutect2, varscan2
- ZNF804A | c.2440C>T p.R814* | Nonsense Mutation (SNP) | VAF 70/219 reads (32%) | catalogued as rs772974941, COSV56437401, COSV56474195; called by muse, mutect2, varscan2
- ATP11C | c.1135T>A p.W379R | Missense Mutation (SNP) | VAF 43/203 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSTF2 | c.1355C>T p.A452V | Missense Mutation (SNP) | VAF 154/813 reads (19%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- CSTL1 | c.340del p.C114Afs*4 | Frame Shift Del (DEL) | VAF 46/173 reads (27%) | called by mutect2, pindel, varscan2
- DNAH9 | c.1997G>T p.W666L | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- DSG3 | c.592del p.I198Lfs*14 | Frame Shift Del (DEL) | VAF 37/162 reads (23%) | called by mutect2, pindel, varscan2
- EHF | c.198C>G p.N66K | Missense Mutation (SNP) | VAF 72/187 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FAM122B | c.155_157del p.T52del | In Frame Del (DEL) | VAF 39/324 reads (12%) | called by pindel, varscan2
- FAM83C | c.1759C>G p.L587V | Missense Mutation (SNP) | VAF 121/437 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FLG | c.9051T>A p.S3017R | Missense Mutation (SNP) | VAF 27/668 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2
- GALNT10 | c.1078A>G p.M360V | Missense Mutation (SNP) | VAF 86/202 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- IGLV4-69 | c.339G>C p.Q113H | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.007); called by muse, varscan2
- ITPR3 | c.4288G>T p.E1430* | Nonsense Mutation (SNP) | VAF 82/224 reads (37%) | called by muse, mutect2, varscan2
- KLHL13 | c.1931C>T p.P644L | Missense Mutation (SNP) | VAF 53/186 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.006); called by muse, varscan2
- MAGEB6 | c.47_48del p.Q16Rfs*35 | Frame Shift Del (DEL) | VAF 8/52 reads (15%) | called by mutect2, pindel, varscan2
- MPHOSPH6 | c.415_422del p.E139* | Frame Shift Del (DEL) | VAF 21/141 reads (15%) | called by mutect2, pindel, varscan2
- MYO3B | c.469G>T p.V157L | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- NCKAP5 | c.3221A>G p.E1074G | Missense Mutation (SNP) | VAF 82/193 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- OR4A16 | c.672A>C p.K224N | Missense Mutation (SNP) | VAF 109/254 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- PEAK1 | c.3424C>A p.Q1142K | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.01); called by muse, mutect2
- PEX1 | c.1588G>T p.V530F | Missense Mutation (SNP) | VAF 68/233 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- PIK3C2A | c.1622G>A p.C541Y | Missense Mutation (SNP) | VAF 46/164 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- PITPNB | c.781G>A p.G261S | Missense Mutation (SNP) | VAF 32/175 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- PLXNB3 | c.2672T>A p.I891N | Missense Mutation (SNP) | VAF 42/194 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- RELN | c.2918G>C p.S973T | Missense Mutation (SNP) | VAF 117/543 reads (22%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- REPS2 | c.1360A>T p.K454* | Nonsense Mutation (SNP) | VAF 53/165 reads (32%) | called by muse, mutect2, varscan2
- RFX1 | c.2673_2675del p.E891_H892delinsD | In Frame Del (DEL) | VAF 75/344 reads (22%) | called by mutect2, pindel, varscan2
- TRABD2B | c.982G>A p.G328R | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZBTB7C | c.1043C>T p.P348L | Missense Mutation (SNP) | VAF 75/172 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- ZNF596 | c.683G>A p.C228Y | Missense Mutation (SNP) | VAF 69/186 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF781 | c.220T>C p.S74P | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.209); called by muse, mutect2
- CACNG3 | c.399C>T p.N133= | Silent (SNP) | VAF 73/225 reads (32%) | catalogued as rs147734423; called by muse, mutect2, varscan2
- ELFN1 | c.1431G>A p.A477= | Silent (SNP) | VAF 68/240 reads (28%) | catalogued as rs1454221842, COSV70034501; called by muse, mutect2, varscan2
- FBN3 | c.4524C>T p.A1508= | Silent (SNP) | VAF 86/320 reads (27%) | catalogued as rs753243238, COSV54466566; called by muse, mutect2, varscan2
- FRMD1 | c.585C>T p.G195= | Silent (SNP) | VAF 53/185 reads (29%) | catalogued as rs375257973; called by muse, mutect2, varscan2
- GDPD2 | c.1467C>A p.T489= | Silent (SNP) | VAF 11/275 reads (4%) | catalogued as rs1350737967; called by muse, mutect2
- GJA3 | c.1221G>A p.P407= | Silent (SNP) | VAF 131/320 reads (41%) | catalogued as rs1416947026; called by muse, mutect2, varscan2
- HOXD4 | c.120C>T p.G40= | Silent (SNP) | VAF 120/313 reads (38%) | called by muse, mutect2, varscan2
- KCNG4 | c.1050G>A p.L350= | Silent (SNP) | VAF 179/447 reads (40%) | called by muse, mutect2, varscan2
- LAT | c.168G>A p.T56= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs754929840; called by muse, mutect2, varscan2
- LCE3E | c.255C>T p.C85= | Silent (SNP) | VAF 76/170 reads (45%) | called by muse, mutect2, varscan2
- LDB3 | c.2037C>T p.G679= | Silent (SNP) | VAF 165/265 reads (62%) | catalogued as rs754386652; called by muse, mutect2, varscan2
- MAST4 | c.5142C>T p.S1714= (on ENST00000403625 / NM_001164664.2; = p.S1525= on NM_015183.3) | Silent (SNP) | VAF 44/139 reads (32%) | called by mutect2, varscan2
- NHS | c.264G>A p.A88= | Silent (SNP) | VAF 124/458 reads (27%) | called by muse, mutect2, varscan2
- NKX2-6 | c.615G>A p.P205= | Silent (SNP) | VAF 180/513 reads (35%) | called by muse, mutect2, varscan2
- OR2W1 | c.93C>T p.V31= | Silent (SNP) | VAF 71/246 reads (29%) | catalogued as rs761069514, COSV65851929; called by muse, mutect2, varscan2
- OR6N1 | c.576G>A p.T192= | Silent (SNP) | VAF 69/198 reads (35%) | catalogued as rs757996854; called by muse, mutect2, varscan2
- PDGFD | c.324C>A p.I108= | Silent (SNP) | VAF 69/179 reads (39%) | catalogued as COSV56388506; called by muse, mutect2
- POLA1 | c.3582G>A p.A1194= | Silent (SNP) | VAF 52/187 reads (28%) | catalogued as rs748084569; called by muse, mutect2, varscan2
- PTCHD3 | c.186G>A p.S62= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as rs1392843137, COSV71256281; called by muse, mutect2, varscan2
- RDH16 | c.24C>T p.F8= | Silent (SNP) | VAF 42/110 reads (38%) | catalogued as rs771014684, COSV100660186; called by muse, mutect2, varscan2
- SDK1 | c.2619G>A p.P873= | Silent (SNP) | VAF 78/244 reads (32%) | catalogued as rs146784103; called by muse, mutect2, varscan2
- SLC9A3R1 | c.57G>A p.K19= | Silent (SNP) | VAF 49/121 reads (40%) | called by muse, mutect2, varscan2
- SSTR1 | c.516C>T p.T172= | Silent (SNP) | VAF 140/346 reads (40%) | catalogued as rs375613085; called by muse, mutect2, varscan2
- TH | c.189G>A p.P63= (on ENST00000381178 / NM_199292.3; = p.P32= on NM_000360.4) | Silent (SNP) | VAF 144/459 reads (31%) | catalogued as rs202167640; ClinVar: likely benign; called by muse, mutect2, varscan2
- TNFRSF11A | c.1632C>T p.G544= | Silent (SNP) | VAF 109/290 reads (38%) | catalogued as rs766202312, COSV54022284; called by muse, mutect2, varscan2
- WDFY4 | c.7596C>T p.P2532= | Silent (SNP) | VAF 100/159 reads (63%) | catalogued as rs540638460, COSV55424442; called by muse, mutect2, varscan2
- ZNF831 | c.1758C>T p.D586= | Silent (SNP) | VAF 34/185 reads (18%) | catalogued as rs968436868, COSV64036891, COSV64041705; called by muse, mutect2, varscan2
- CCDC144A | c.1715+16C>T | Intron (SNP) | VAF 64/203 reads (32%) | catalogued as rs923381266; called by muse, mutect2, varscan2
- DNAH7 | c.1353+1498C>A | Intron (SNP) | VAF 50/118 reads (42%) | called by muse, mutect2, varscan2
- ENPP1 | c.1893+10G>A | Intron (SNP) | VAF 60/226 reads (27%) | catalogued as rs767778451; called by muse, mutect2, varscan2
- EYS | c.1767-6642G>A | Intron (SNP) | VAF 196/823 reads (24%) | catalogued as rs770019576; called by muse, mutect2, varscan2
- HSD17B4 | c.1512+226A>T | Intron (SNP) | VAF 24/92 reads (26%) | called by muse, mutect2
- LCLAT1 | c.479-9647C>A | Intron (SNP) | VAF 16/37 reads (43%) | called by muse, mutect2, varscan2
- LINC00269 | n.668C>T | RNA (SNP) | VAF 10/36 reads (28%) | catalogued as rs1027538505; called by mutect2, varscan2
- MAX | c.37-10_37-9del | Intron (DEL) | VAF 58/251 reads (23%) | called by pindel, varscan2
- NFIC | c.*20C>T | 3'UTR (SNP) | VAF 62/258 reads (24%) | called by muse, mutect2, varscan2
- PDGFA | c.*65G>T | 3'UTR (SNP) | VAF 75/283 reads (27%) | called by muse, mutect2, varscan2
- RBMX | c.110-46A>G | Intron (SNP) | VAF 73/305 reads (24%) | called by muse, mutect2, varscan2
